Somatic mutation profile of tumor specimen TCGA-BR-4188-01A (aliquot TCGA-BR-4188-01A-01D-1126-08) from TCGA case TCGA-BR-4188, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; Tumor grade: G3; Age at diagnosis: 53.6 years (19,585 days).
Specimen TCGA-BR-4188-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69dbfe7c-3efc-4126-b36d-2b59aca7a16d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4188-11A (Solid Tissue Normal), aliquot TCGA-BR-4188-11A-01D-1126-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c434060-b4f7-4b0e-b8d9-939f740fc72e

The open-access MAF lists 85 somatic variants for this specimen: 63 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 20, Frame Shift Ins 2, Nonsense Mutation 2, Frame Shift Del 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1723G>A p.G575R | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs797044875, CM162169, COSV62690253; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RHOA | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 39/87 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1057519954, COSV69041523, COSV69041892, COSV69042190; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.2564C>G p.S855C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54385656; called by muse, mutect2, varscan2
- AGPAT3 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as rs771718555, COSV52367940; called by muse, mutect2, varscan2
- AKAP4 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV62073768; called by muse, mutect2, varscan2
- AMOT | c.1888C>T p.R630* (on ENST00000371959 / NM_001113490.1; = p.R221* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 13/117 reads (11%) | catalogued as rs1324919699, COSV59060824; called by muse, mutect2, varscan2
- C3orf20 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs777709119, COSV53782660; called by muse, mutect2, varscan2
- CD7 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs781565740, COSV53938342; called by mutect2, varscan2
- CDH1 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55727861, COSV55728037; called by muse, mutect2, varscan2
- CSMD3 | c.4319G>A p.R1440H (on ENST00000297405 / NM_001363185.1; = p.R1336H on NM_052900.3) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.976); catalogued as rs756361881, COSV52108899; called by mutect2, varscan2
- CTNNA2 | c.2302G>T p.D768Y | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58136474; called by muse, mutect2, varscan2
- DCAF12L2 | c.791A>G p.K264R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as COSV63580410, COSV63581364; called by muse, mutect2, varscan2
- DCDC1 | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs377035186, COSV60839331; called by muse, mutect2, varscan2
- DMBT1 | c.7357G>A p.V2453M (on ENST00000338354 / NM_001377530.1; = p.V1696M on NM_004406.3) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs372434439; called by muse, mutect2, varscan2
- DMXL1 | c.1612G>A p.D538N | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60705427; called by muse, mutect2, varscan2
- DNAH5 | c.9332T>C p.I3111T | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs777061272, COSV54205507; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1655C>T p.T552M | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200653424; called by muse, mutect2, varscan2
- ESR1 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs766779326, COSV52781525; called by muse, mutect2, varscan2
- FAT2 | c.8182C>T p.R2728W | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs201629483; called by muse, mutect2, varscan2
- FAT2 | c.4750C>T p.R1584W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs368074191; called by mutect2, varscan2
- FSTL4 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99534068; called by muse, mutect2, varscan2
- GP1BA | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.098); catalogued as COSV56698674; called by muse, mutect2, varscan2
- GPR101 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.025); catalogued as COSV53237533; called by muse, mutect2, varscan2
- GRID1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.968); catalogued as COSV60015215; called by muse, mutect2
- GRM1 | c.3328G>A p.V1110M | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs373321710; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HIRA | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs193106800, COSV54272308; called by muse, mutect2, varscan2
- HS3ST2 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746835350, COSV54457793; called by muse, mutect2, varscan2
- IFT22 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs140464086, COSV59526851; called by muse, mutect2, varscan2
- IGHE | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs782632998; called by muse, varscan2
- KLHL24 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.044); catalogued as COSV54424770; called by muse, mutect2, varscan2
- KRT16 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs762278898, COSV56967089; called by muse, varscan2
- LHCGR | c.1415T>C p.I472T | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV54293039; called by muse, mutect2, varscan2
- LRRTM1 | c.1299G>T p.M433I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV54438421; called by muse, mutect2, varscan2
- LTBP1 | c.3983G>A p.R1328H (on ENST00000404816 / NM_206943.4; = p.R1002H on NM_000627.4) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as rs139673362; called by mutect2, varscan2
- MALT1 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | catalogued as COSV61934130; called by muse, varscan2
- MECP2 | c.55C>G p.Q19E | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as HM971529, COSV57652009; called by muse, mutect2, varscan2
- MYO1D | c.2747T>C p.L916P | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1445738159, COSV59007858; called by muse, mutect2, varscan2
- NID1 | c.1087C>A p.Q363K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV51615296; called by muse, mutect2, varscan2
- OSBPL7 | c.827T>A p.L276Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50106781; called by muse, mutect2, varscan2
- PCDH10 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as COSV52087995; called by muse, mutect2, varscan2
- PCDHA3 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV63540702; called by muse, mutect2, varscan2
- PCDHB16 | c.2030C>G p.A677G | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); catalogued as COSV53358143; called by muse, mutect2, varscan2
- PCYT1A | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771371499, COSV53056065; called by muse, mutect2, varscan2
- PDE9A | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1164261824, COSV52322876; called by muse, mutect2, varscan2
- PEX5 | c.1439G>A p.R480Q (on ENST00000420616; = p.R472Q on NM_000319.5) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs759523235, COSV56953541; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNC1 | c.3383G>A p.R1128H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51569838; called by muse, mutect2, varscan2
- PPM1D | c.1535dup p.N512Kfs*16 | Frame Shift Ins (INS) | VAF 12/90 reads (13%) | catalogued as rs763475304; called by mutect2, varscan2
- RAPGEF4 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs770406565, COSV51379753; called by muse, mutect2, varscan2
- RASAL2 | c.2114G>A p.R705Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs753532224, COSV62710160; called by muse, mutect2, varscan2
- RLN3 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs141631429; called by mutect2, varscan2
- TACC2 | c.7519G>A p.E2507K (on ENST00000334433; = p.E585K on NM_006997.4) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV53276716; called by muse, mutect2, varscan2
- TACR3 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV59198388; called by muse, mutect2, varscan2
- TANC2 | c.5358C>G p.S1786R | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV67330515; called by muse, mutect2, varscan2
- THEMIS | c.920T>C p.I307T | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs779555672, COSV100965421, COSV64069356; called by muse, mutect2, varscan2
- THOC2 | c.4078G>C p.E1360Q | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.203); catalogued as COSV55540850; called by muse, mutect2, varscan2
- TPCN1 | c.2167G>A p.V723I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs534081134, COSV59237749; called by muse, mutect2, varscan2
- TRO | c.3083G>T p.G1028V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV51497917; called by muse, mutect2, varscan2
- TTN | c.76199C>T p.T25400M (on ENST00000591111; = p.T17976M on NM_003319.4) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | PolyPhen benign (0.251); catalogued as rs755178087, COSV59901973; called by muse, mutect2, varscan2
- VAT1L | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as rs763091067, COSV56814847, COSV56821403; called by muse, mutect2, varscan2
- ZHX2 | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58710516; called by muse, mutect2, varscan2
- ZNF714 | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV99395688; called by muse, mutect2, varscan2
- ARID1A | c.6109dup p.Q2037Pfs*62 | Frame Shift Ins (INS) | VAF 21/75 reads (28%) | called by mutect2, pindel, varscan2
- VPS35 | c.306_321del p.N103Ffs*4 | Frame Shift Del (DEL) | VAF 8/102 reads (8%) | called by mutect2, pindel
- ANKRD44 | c.1767G>A p.S589= | Silent (SNP) | VAF 35/224 reads (16%) | catalogued as rs771826807, COSV56549908, COSV56561302; called by muse, mutect2, varscan2
- AURKC | c.120C>T p.V40= (on ENST00000302804 / NM_001015878.2; = p.V6= on NM_003160.3) | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs1456767327, COSV57137069; called by muse, mutect2, varscan2
- C2orf80 | c.192G>A p.L64= | Silent (SNP) | VAF 15/160 reads (9%) | catalogued as COSV58015553; called by muse, mutect2
- DNAH9 | c.6567G>A p.E2189= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1463019030, COSV52335567; called by muse, mutect2, varscan2
- FLG | c.11250G>A p.A3750= | Silent (SNP) | VAF 92/420 reads (22%) | catalogued as rs201725426, COSV64239015; called by muse, varscan2
- GCM2 | c.441C>T p.N147= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs1262487190, COSV65275133; called by muse, mutect2, varscan2
- HMCN1 | c.12327C>T p.D4109= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV54879424; called by muse, mutect2, varscan2
- KCNA1 | c.723C>T p.F241= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs147731985, COSV66836616; called by muse, varscan2
- KCNV1 | c.321G>A p.S107= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV52084736; called by muse, mutect2, varscan2
- LRIG1 | c.969C>T p.D323= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs534184911, COSV56237119; called by mutect2, varscan2
- MYCBP2 | c.3342G>A p.A1114= (on ENST00000357337; = p.A1152= on NM_015057.5) | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs184772749, COSV62011039; called by muse, mutect2, varscan2
- NBEA | c.8499C>T p.S2833= | Silent (SNP) | VAF 27/153 reads (18%) | catalogued as rs770305071, COSV59762254; called by muse, mutect2, varscan2
- NEFL | c.1185C>T p.G395= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs751512030, COSV55336290; ClinVar: uncertain significance; called by mutect2, varscan2
- OR5L1 | c.489T>C p.A163= | Silent (SNP) | VAF 37/176 reads (21%) | catalogued as COSV61732863; called by muse, mutect2, varscan2
- PCDHAC1 | c.1164G>A p.T388= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs183490994, COSV53838154; called by muse, mutect2, varscan2
- SALL1 | c.1836C>T p.A612= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs747254638, COSV51753661; called by muse, varscan2
- TIAM1 | c.4704C>T p.S1568= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs755574864, COSV54538748; called by mutect2, varscan2
- TNC | c.627C>T p.D209= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs138151398; called by mutect2, varscan2
- TTLL9 | c.795C>T p.Y265= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV60589834; called by muse, mutect2, varscan2
- UNC45A | c.1704G>A p.A568= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs139418696, COSV67815867; called by muse, mutect2, varscan2
- DKC1 | c.771+149T>A | Intron (SNP) | VAF 16/116 reads (14%) | catalogued as COSV101059910; called by muse, mutect2, varscan2
- XIST | n.8301C>T | RNA (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
